FM case AD10813 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Other and unspecified urinary organs.
https://portal.gdc.cancer.gov/cases/84c44060-2446-4d41-85f0-a04f9eeadb6f

Male, 74.2 years: Urothelial carcinoma, NOS (ICD-O-3 8120/3) of the urethra; metastasis biopsied or resected from the pelvis. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
